Somatic mutation profile of tumor specimen ALCH-B1OV-TTP1-A (aliquot ALCH-B1OV-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1OV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.7 years (25,830 days).
Specimen ALCH-B1OV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8a2be37-6358-4814-9135-1582de8e0b37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OV-NB1-A (Blood Derived Normal), aliquot ALCH-B1OV-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/519842a2-ead0-4aa6-b7dc-f196e08ae632

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Intron 4, Nonsense Mutation 3, 3'UTR 2, RNA 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 355/525 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 32/122 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARPP21 | c.2168T>C p.M723T | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1228802895; called by muse, mutect2
- C20orf194 | c.2864A>G p.Y955C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.808); catalogued as rs561755293; called by muse, mutect2
- CSMD3 | c.8810G>T p.G2937V (on ENST00000297405 / NM_001363185.1; = p.G2768V on NM_052900.3) | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52332589; called by muse, mutect2
- DHX38 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777467018, COSV99194305; called by muse, mutect2
- DPPA2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs748847987, COSV101524741, COSV72118040; called by muse, mutect2, varscan2
- EAPP | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759579369, COSV99164224; called by muse, mutect2
- ELFN1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163244033; called by muse, mutect2
- GEN1 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV58057446; called by muse, mutect2
- KCTD16 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1422003230, COSV72579656, COSV72580338; called by muse, mutect2
- NEB | c.2083A>G p.K695E | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.452); catalogued as rs774293740; called by muse, mutect2, varscan2
- NLRP12 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.237); catalogued as COSV60743829, COSV99048056; called by muse, mutect2, varscan2
- NOS1 | c.1890G>A p.W630* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV57620278; called by muse, mutect2, varscan2
- OR5D16 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101004152; called by muse, mutect2, varscan2
- OSMR | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs373299489; called by muse, mutect2, varscan2
- PI4KB | c.821G>A p.R274H (on ENST00000368873 / NM_001369623.1; = p.R286H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761617123, COSV55021204; called by muse, mutect2, varscan2
- RBFOX1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs373077021; ClinVar: uncertain significance; called by mutect2, varscan2
- RNPC3 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV71077435; called by muse, mutect2, varscan2
- TXLNB | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs764882772; called by muse, mutect2, varscan2
- ZEB1 | c.2530A>G p.T844A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs1365284074; called by muse, mutect2, varscan2
- AL096814.1 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); called by muse, mutect2
- CCDC138 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); called by muse, mutect2
- HDAC6 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 48/138 reads (35%) | called by muse, mutect2, varscan2
- HDAC8 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HDAC8 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- HMGXB3 | c.1115C>T p.P372L (on ENST00000613459; = p.P126L on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IQGAP3 | c.3313G>T p.A1105S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRP1B | c.9909C>G p.N3303K | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LUZP2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- MTRF1 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- OR13C3 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- OR8H1 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PGGT1B | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTBP3 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- R3HCC1 | c.143G>C p.G48A (on ENST00000411463; = p.G8A on NM_001136108.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAG1 | c.3044C>G p.S1015C | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ST6GALNAC2 | c.870_872del p.K291del | In Frame Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- ZMAT1 | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- ZNF592 | c.3488C>G p.T1163S | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNDBP1 | c.435G>A p.E145= | Silent (SNP) | VAF 31/193 reads (16%) | called by muse, mutect2, varscan2
- DCDC1 | c.3231A>G p.E1077= (on ENST00000597505 / NM_001367979.1; = p.E184= on NM_020869.3) | Silent (SNP) | VAF 27/519 reads (5%) | catalogued as COSV60313779; called by muse, mutect2
- HS3ST6 | c.999G>A p.Q333= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53537028; called by muse, mutect2, varscan2
- HUWE1 | c.3642G>A p.T1214= | Silent (SNP) | VAF 18/319 reads (6%) | catalogued as rs782459307, COSV99469953; called by muse, mutect2
- PARP4 | c.2058G>A p.K686= | Silent (SNP) | VAF 35/165 reads (21%) | called by muse, varscan2
- TENM4 | c.951C>T p.P317= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs771901691; called by muse, mutect2, varscan2
- ZMAT1 | c.726C>T p.F242= | Silent (SNP) | VAF 23/460 reads (5%) | called by muse, mutect2
- CASC15 | chr6:22146702 G>A | 5'Flank (SNP) | VAF 16/132 reads (12%) | catalogued as rs1160459147; called by muse, mutect2
- CLASP1 | c.196-560A>G | Intron (SNP) | VAF 3/44 reads (7%) | catalogued as rs1208611147; called by muse, mutect2
- DCAF6 | c.1378+11106C>A | Intron (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- DOCK6 | c.309-29_309-28del | Intron (DEL) | VAF 12/84 reads (14%) | called by pindel, varscan2
- GUSBP10 | n.246G>A | RNA (SNP) | VAF 13/73 reads (18%) | catalogued as rs755431047; called by muse, mutect2, varscan2
- OR56B3P | n.290G>A | RNA (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*340del | 3'UTR (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- RAD50 | c.*667_*668del | 3'UTR (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2
- ZBP1 | c.1094-2397T>C | Intron (SNP) | VAF 35/327 reads (11%) | called by muse, mutect2, varscan2
